TARGET case TARGET-10-PASUWG — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a74dba1a-afd7-4b0f-9eb4-e21ed8f73b6d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 6 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 6.0 years (2,199 days); Year of diagnosis: 2009; Days to last follow up: 2,357 days (6.5 years).
   Treatment given: Protocol identifier: AALL0232.

Follow-up (1 entry)
- Days to follow up: 2,357 days (6.5 years); Event-free: no event (relapse, second malignancy or death) recorded through day 2,357; Year of follow up: 2015.

Molecular and laboratory tests (laboratory values grouped by visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- BCR–ABL1 fusion: Negative.
- ETV6–RUNX1 fusion (FISH): Negative.
- KMT2A rearrangement (FISH): Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 329 ×10³/µL.
- Day 8: Minimal Residual Disease (Flow Cytometry) 0.35%.
- Day 15: Bone Marrow blast count 0%.
- Day 29: Bone Marrow blast count 1%; Minimal Residual Disease (Flow Cytometry) 0%.

Biospecimens (3 samples)
- Samples TARGET-10-PASUWG-03A, TARGET-10-PASUWG-03B (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
- Sample TARGET-10-PASUWG-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Dicentric_20230727.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 2357
- WBC at Diagnosis: 329.2
- CNS Status at Diagnosis: CNS 1
- Testicular Involvement: No
- MRD Day 8: 0.35
- MRD Day 8 Sensitivity: 0.01
- MRD Day 29: 0
- MRD Day 29 Sensitivity: 0.01
- ETV6 RUNX1 Fusion Status: Negative
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 15: 0
- BMA Blasts Day 29: 1
- Karyotype: 45,XY,add(5)(q31),del(7)(p12p15),dic(9;20)(p13;q11.2),del(11)(q23q25),del(12)(p12p13),del(13)(q12q22)[20]
- DNA Index: 1.1746
- Cell of Origin: B-Precursor
